Surgical pathology report (de-identified scan), TCGA case TCGA-2G-AAIF, project TCGA-TGCT (Testicular Germ Cell Tumors), specimen TCGA-2G-AAIF-01A (Primary Tumor).

Department of Pathology

Direct dial

Mobile:

Internal postal address

E-mail

Date

Concerning

Postal address

Street address

Summary pathology report

Right orchiectomy; seminoma; diameter 2.5 cm; no angio-invasion present; no invasion in rete testis; lymphatic invasion present; no invasion of tunica albuginea; epididymis free of tumor; surgical margin of spermatic cord free of tumor.

Date of procurement (= date of orchiectomy):

ICD-O-3
Seminoma NOS 9061/3
Site: Testis NOS C62.9
JN 3/7/14

pathologist

professor of pathology

Source: NCI Genomic Data Commons file 3ae2c573-ee79-423e-b1c4-d16c65371f6e (TCGA-2G-AAIF-01A.pdf), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).